Somatic mutation profile of tumor specimen MMRF_1092_1_BM_CD138pos (aliquot MMRF_1092_1_BM_CD138pos_T2_TSE61_K02710) from MMRF case MMRF_1092, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.4 years (25,331 days).
Specimen MMRF_1092_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b920127-9973-4af7-91eb-c0effd5ab051.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1092_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1092_1_PB_Whole_C1_TSE61_K02717; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ace3bcc3-39ce-4cd1-8f17-d9caf1c1f1c7

The open-access MAF lists 109 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 38, Silent 12, 5'UTR 6, 5'Flank 4, Nonsense Mutation 2, Intron 2, Frame Shift Del 2, Splice Region 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 45/88 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAMSAP3 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs748364539; called by muse, mutect2, varscan2
- CDH4 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1219004668; called by muse, mutect2, varscan2
- EPHB3 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1198054446; called by muse, mutect2, varscan2
- ERAL1 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as rs201165120; called by muse, mutect2, varscan2
- FAT3 | c.7760G>A p.R2587K | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.578); catalogued as COSV53105292; called by muse, mutect2, varscan2
- GPRC5D | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs563190193; called by muse, mutect2, varscan2
- GTF2IRD1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as rs139144176, COSV56086308; called by muse, mutect2, varscan2
- HTRA1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.82); catalogued as rs765112668, COSV64564070; called by muse, mutect2, varscan2
- JMY | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as rs1320011875; called by muse, mutect2
- LRRC49 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 21/138 reads (15%) | catalogued as rs1424525041; called by muse, mutect2, varscan2
- MTHFD2L | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs575932490, COSV57470302; called by muse, mutect2, varscan2
- NCKAP5 | c.5435C>T p.A1812V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs764362331; called by muse, mutect2
- PCDH9 | c.3385T>G p.C1129G (on ENST00000377865 / NM_203487.3; = p.C1095G on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV60579591; called by muse, mutect2, varscan2
- PSD | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV99192842; called by muse, mutect2, varscan2
- SNRK | c.2295C>G p.I765M | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as COSV56069282; called by muse, mutect2, varscan2
- SRRM2 | c.2750C>A p.P917H | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as rs1349958738, COSV57081374; called by muse, mutect2, varscan2
- TAAR2 | c.913T>C p.Y305H (on ENST00000367931 / NM_001033080.1; = p.Y260H on NM_014626.3) | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780947675; called by muse, mutect2, varscan2
- ZIC2 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 45/47 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs755198296, COSV66255471; called by muse, mutect2, varscan2
- ALDH8A1 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANGEL2 | c.1385C>A p.T462N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKRD20A4P | c.1619_1623del p.N540Ifs*3 | Frame Shift Del (DEL) | VAF 21/157 reads (13%) | called by mutect2, varscan2
- BIVM-ERCC5 | c.4574A>C p.K1525T | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CCNG1 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CFAP74 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EMSY | c.3576G>T p.M1192I | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM169A | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FAM186B | c.2204A>G p.K735R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FASTK | c.1295T>C p.F432S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GRAMD1A | c.327T>G p.D109E | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- GRM7 | c.77G>T p.C26F | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IL16 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- LMTK2 | c.2801A>C p.H934P | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGI2 | c.2682del p.N895Tfs*45 | Frame Shift Del (DEL) | VAF 10/110 reads (9%) | called by mutect2, pindel
- MPHOSPH6 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MYO1B | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 48/82 reads (59%) | called by muse, mutect2, varscan2
- NBEA | c.4127T>C p.I1376T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- NUGGC | c.58T>G p.Y20D | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2
- NUTM1 | c.2336G>A p.G779E | Missense Mutation (SNP) | VAF 133/243 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PTPN23 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RRP1B | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLAMF6 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SND1 | c.1971C>T p.V657= | Splice Region (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- TRIP6 | c.221T>A p.V74E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YY1AP1 | c.2141C>T p.S714F (on ENST00000295566 / NM_139118.2; = p.S657F on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ANKRD36B | c.468G>A p.L156= | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- CAMTA2 | c.1575C>A p.T525= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- CCR10 | c.756G>A p.L252= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- CMYA5 | c.5484T>G p.L1828= | Silent (SNP) | VAF 71/249 reads (29%) | catalogued as rs756040705; called by muse, mutect2, varscan2
- KCTD15 | c.618C>T p.N206= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- LPAR3 | c.369C>T p.I123= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as rs989829274, COSV65453489; called by muse, mutect2
- NGLY1 | c.1578T>G p.S526= | Silent (SNP) | VAF 13/72 reads (18%) | called by muse, varscan2
- NLRP13 | c.189C>T p.A63= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs758086091, COSV100738257, COSV61622026; called by muse, mutect2
- PCDHGA7 | c.1773G>A p.V591= | Silent (SNP) | VAF 37/516 reads (7%) | catalogued as rs1316537355; called by muse, mutect2
- REX1BD | c.336C>T p.A112= | Silent (SNP) | VAF 34/41 reads (83%) | called by muse, mutect2, varscan2
- SLC2A14 | c.1287C>T p.A429= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs772402834, COSV61587039; called by muse, mutect2, varscan2
- ZNF646 | c.3714C>T p.G1238= | Silent (SNP) | VAF 51/88 reads (58%) | catalogued as COSV54926312; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499468 T>C | 5'Flank (SNP) | VAF 22/68 reads (32%) | catalogued as rs749230382; called by muse, mutect2
- AP000769.5 | chr11:65499568 T>C | 5'Flank (SNP) | VAF 16/30 reads (53%) | called by muse, varscan2
- CCDC32 | chr15:40532261 C>A | 3'Flank (SNP) | VAF 44/186 reads (24%) | called by muse, mutect2, varscan2
- CLEC3A | c.*730A>C | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- DNALI1 | c.*1373C>T | 3'UTR (SNP) | VAF 72/141 reads (51%) | called by muse, mutect2, varscan2
- EXOC5 | c.*2227del | 3'UTR (DEL) | VAF 21/78 reads (27%) | called by pindel, varscan2
- GATA4 | c.*1490_*1495del | 3'UTR (DEL) | VAF 33/83 reads (40%) | called by mutect2, pindel, varscan2
- GSK3B | c.*3616del | 3'UTR (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- HLA-DOB | c.*309A>G | 3'UTR (SNP) | VAF 46/112 reads (41%) | catalogued as rs557195146; called by muse, mutect2, varscan2
- INMT | c.*465_*469del | 3'UTR (DEL) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- JADE2 | c.*782C>T | 3'UTR (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- JMY | c.*2504A>C | 3'UTR (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- JOSD1 | c.*2111A>C | 3'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- JOSD1 | c.*2007A>C | 3'UTR (SNP) | VAF 64/158 reads (41%) | called by muse, mutect2, varscan2
- LAMTOR4 | c.*29C>T | 3'UTR (SNP) | VAF 22/135 reads (16%) | catalogued as rs746865428; called by muse, mutect2, varscan2
- LEF1 | c.*518T>C | 3'UTR (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- LRRCC1 | c.*564T>G | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- LUZP2 | c.*2190dup | 3'UTR (INS) | VAF 32/128 reads (25%) | catalogued as rs929629842; called by mutect2, varscan2
- LYST | c.*948del | 3'UTR (DEL) | VAF 27/95 reads (28%) | called by mutect2, pindel, varscan2
- MAN2A1 | c.-455C>T | 5'UTR (SNP) | VAF 12/56 reads (21%) | catalogued as rs1017363152; called by muse, mutect2
- MGAT5 | c.*587A>G | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- MIR296 | chr20:58819253 ins C | 5'Flank (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- MMGT1 | c.-154C>T | 5'UTR (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- NR4A2 | c.*204C>G | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- NUDT3 | c.*481C>G | 3'UTR (SNP) | VAF 34/66 reads (52%) | catalogued as rs1312523453; called by muse, mutect2, varscan2
- NXNL1 | c.-46C>T | 5'UTR (SNP) | VAF 69/114 reads (61%) | catalogued as rs1198005737; called by muse, mutect2, varscan2
- ORAI2 | c.*4166A>G | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- PCDH11X | c.-535T>A | 5'UTR (SNP) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- PDE10A | c.*4291G>A | 3'UTR (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- PTCH1 | c.*2274T>A | 3'UTR (SNP) | VAF 7/35 reads (20%) | catalogued as rs540760892, COSV100109821; called by muse, varscan2
- RALGPS1 | c.*1450G>A | 3'UTR (SNP) | VAF 35/186 reads (19%) | called by muse, mutect2, varscan2
- RAP2B | c.*759A>G | 3'UTR (SNP) | VAF 11/66 reads (17%) | catalogued as rs1476388318; called by muse, mutect2, varscan2
- RERE | c.*1857del | 3'UTR (DEL) | VAF 70/135 reads (52%) | catalogued as rs1045141505; called by mutect2, varscan2
- SCNN1D | c.*211G>A | 3'UTR (SNP) | VAF 47/90 reads (52%) | catalogued as rs1158942457; called by muse, mutect2, varscan2
- SHC3 | c.*303_*304del | 3'UTR (DEL) | VAF 6/42 reads (14%) | catalogued as rs749540477; called by pindel, varscan2
- SLC46A3 | c.-3A>C | 5'UTR (SNP) | VAF 37/37 reads (100%) | called by muse, mutect2, varscan2
- SP110 | c.-55T>C | 5'UTR (SNP) | VAF 53/109 reads (49%) | called by muse, mutect2, varscan2
- SPON2 | c.-239+7128del | Intron (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- SYNGR2 | c.*192T>C | 3'UTR (SNP) | VAF 148/311 reads (48%) | called by muse, mutect2, varscan2
- SYT4 | c.*2417G>A | 3'UTR (SNP) | VAF 49/86 reads (57%) | called by muse, mutect2, varscan2
- TAS2R5 | c.*71T>G | 3'UTR (SNP) | VAF 52/198 reads (26%) | called by muse, mutect2, varscan2
- TBC1D13 | c.*572G>A | 3'UTR (SNP) | VAF 14/47 reads (30%) | catalogued as rs1220897939; called by muse, mutect2, varscan2
- TCF4 | c.*5578A>C | 3'UTR (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- TENM3 | c.*2466G>T | 3'UTR (SNP) | VAF 33/61 reads (54%) | catalogued as rs1421092638; called by muse, mutect2, varscan2
- TLCD4 | c.*363G>A | 3'UTR (SNP) | VAF 10/23 reads (43%) | catalogued as rs1467161779; called by muse, mutect2, varscan2
- TMEM99 | n.800G>A | RNA (SNP) | VAF 81/162 reads (50%) | catalogued as rs528693743; called by muse, mutect2, varscan2
- TXNDC5 | c.*308A>C | 3'UTR (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
- ZBTB11 | chr3:101677569 A>C | 5'Flank (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- ZBTB44 | c.1687-258_1687-257del | Intron (DEL) | VAF 70/273 reads (26%) | called by mutect2, pindel, varscan2
- ZNF525 | c.*1733C>T | 3'UTR (SNP) | VAF 93/432 reads (22%) | called by muse, mutect2, varscan2
- ZNF529 | c.*1007T>A | 3'UTR (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- ZNF829 | c.*41A>T | 3'UTR (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2
